Somatic mutation profile of tumor specimen C3L-00157-02 (aliquot CPT0002560009) from CPTAC case C3L-00157, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G3; Age at diagnosis: 60.6 years (22,118 days).
Specimen C3L-00157-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8344f7c1-f805-4a3f-bd1b-2a86977d8ac8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00157-71 (Blood Derived Normal), aliquot CPT0008040002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2a9d469-4fca-4198-b90d-f8c0b13de192

The open-access MAF lists 46 somatic variants for this specimen: 28 protein-altering or splice-affecting, 9 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 9, Intron 3, 5'UTR 2, Frame Shift Ins 2, RNA 2, 3'Flank 1, Splice Site 1, Frame Shift Del 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GABRR1 | c.1109C>T p.T370I | Missense Mutation (SNP) | VAF 104/367 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1236615217; called by muse, mutect2, varscan2
- IRX2 | c.1399G>A p.V467I | Missense Mutation (SNP) | VAF 89/271 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs750137642; called by muse, mutect2, varscan2
- KRT36 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 37/448 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.418); catalogued as rs1463086012, COSV60203521; called by muse, mutect2
- MAST1 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 39/254 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1178062265; called by muse, mutect2, varscan2
- MTSS1 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 166/532 reads (31%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.644); catalogued as rs551211348; called by muse, mutect2, varscan2
- POLD3 | c.1369G>C p.V457L | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as rs201676741; called by muse, mutect2, varscan2
- PPP1R3F | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1392791323; called by muse, mutect2
- SCN5A | c.2894G>A p.R965H | Missense Mutation (SNP) | VAF 34/257 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs199473181, CM067021, CM097656, COSV61121747; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- SOX3 | c.995G>A p.G332D | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.601); catalogued as COSV65168434; called by muse, mutect2, varscan2
- TGM7 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs543125845; called by muse, mutect2, varscan2
- TTL | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs780073175, COSV51974451; called by muse, mutect2, varscan2
- ZAN | c.4942C>T p.L1648F | Missense Mutation (SNP) | VAF 93/399 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as COSV61814212; called by muse, mutect2, varscan2
- AL713999.2 | c.524C>G p.S175C | Missense Mutation (SNP) | VAF 77/291 reads (26%) | called by muse, mutect2, varscan2
- CHML | c.1837C>A p.P613T | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL20A1 | c.1570G>T p.D524Y | Missense Mutation (SNP) | VAF 247/640 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- FAM184B | c.1057G>C p.E353Q | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- LPCAT3 | c.85A>T p.N29Y | Missense Mutation (SNP) | VAF 155/557 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- LTBP3 | c.661+1G>A p.X221_splice | Splice Site (SNP) | VAF 56/538 reads (10%) | called by muse, mutect2, varscan2
- MAST1 | c.3231C>A p.N1077K | Missense Mutation (SNP) | VAF 95/403 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- MDH1 | c.736G>C p.A246P | Missense Mutation (SNP) | VAF 93/361 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MS4A7 | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- NBEAL2 | c.6834G>C p.E2278D | Missense Mutation (SNP) | VAF 111/361 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- NUMA1 | c.3962G>T p.R1321L | Missense Mutation (SNP) | VAF 74/844 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.668); called by muse, mutect2
- PIK3R1 | c.1398dup p.Y467Ifs*2 (on ENST00000521381 / NM_181523.3; = p.Y197Ifs*2 on NM_181504.4) | Frame Shift Ins (INS) | VAF 26/70 reads (37%) | called by mutect2, pindel, varscan2
- TP53 | c.686_687del p.C229Yfs*10 | Frame Shift Del (DEL) | VAF 146/403 reads (36%) | called by mutect2, pindel, varscan2
- TRIM28 | c.1374C>G p.Y458* | Nonsense Mutation (SNP) | VAF 58/400 reads (15%) | called by muse, mutect2, varscan2
- TRMT1 | c.358T>G p.S120A | Missense Mutation (SNP) | VAF 108/370 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZKSCAN2 | c.1980_1981insAGTAA p.D661Sfs*17 | Frame Shift Ins (INS) | VAF 19/65 reads (29%) | called by mutect2, pindel, varscan2
- ALS2 | c.3831A>G p.K1277= | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as rs754421607; called by muse, mutect2
- DHX36 | c.2997G>A p.P999= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs771987313; called by muse, mutect2, varscan2
- DIABLO | c.225A>G p.Q75= (on ENST00000443649 / NM_001278303.1; = p.Q148= on NM_019887.6) | Silent (SNP) | VAF 34/261 reads (13%) | catalogued as rs183090944; called by muse, mutect2, varscan2
- IRS2 | c.1804C>A p.R602= | Silent (SNP) | VAF 10/80 reads (13%) | called by muse, mutect2, varscan2
- KRT14 | c.1269C>T p.D423= | Silent (SNP) | VAF 28/430 reads (7%) | catalogued as rs368191932; called by muse, mutect2
- NHS | c.309G>A p.A103= | Silent (SNP) | VAF 62/324 reads (19%) | called by muse, varscan2
- OR5D14 | c.606C>T p.F202= | Silent (SNP) | VAF 17/147 reads (12%) | catalogued as rs866261956; called by muse, mutect2, varscan2
- PTPRF | c.2535A>G p.E845= | Silent (SNP) | VAF 70/494 reads (14%) | called by muse, mutect2, varscan2
- ZCCHC2 | c.474G>T p.P158= | Silent (SNP) | VAF 77/193 reads (40%) | called by muse, mutect2, varscan2
- AL049777.1 | n.510+4443G>C | Intron (SNP) | VAF 23/223 reads (10%) | called by muse, mutect2, varscan2
- ANXA4 | c.-19C>G | 5'UTR (SNP) | VAF 36/212 reads (17%) | catalogued as COSV101268852; called by muse, mutect2, varscan2
- LINC01548 | n.375C>T | RNA (SNP) | VAF 79/321 reads (25%) | catalogued as rs1021437445; called by muse, mutect2, varscan2
- MAPK15 | c.722-17_722-15del | Intron (DEL) | VAF 109/433 reads (25%) | called by pindel, varscan2
- MUC2 | chr11:1094714 A>G | 3'Flank (SNP) | VAF 90/738 reads (12%) | called by muse, varscan2
- MYH16 | n.2435C>T | RNA (SNP) | VAF 115/434 reads (26%) | catalogued as rs1260491326; called by muse, mutect2, varscan2
- PRRG3 | c.*4307C>T | 3'UTR (SNP) | VAF 14/208 reads (7%) | called by muse, mutect2
- SLITRK1 | c.-23G>T | 5'UTR (SNP) | VAF 30/186 reads (16%) | catalogued as COSV100999761; called by muse, mutect2, varscan2
- TMEM240 | c.164+20C>A | Intron (SNP) | VAF 52/326 reads (16%) | called by muse, mutect2, varscan2
